Gene-level copy-number profile of tumor specimen TCGA-SG-A6Z4-01A from TCGA case TCGA-SG-A6Z4, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Undifferentiated sarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 47.6 years (17,368 days).
Specimen TCGA-SG-A6Z4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.16a00020-a856-4c90-8b5f-c8907b243df5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-SG-A6Z4-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4b95a2af-3590-4d56-a453-48f01bc66290

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 1,051; copy number 2: 22,102; copy number 3: 13,657; copy number 4: 19,388; copy number 5: 2,533; copy number 6: 1,077.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-SG-A6Z4-01A-22D-A33D-01): tumor purity 0.81, ploidy 3.05, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,610 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–204,558,120, 1,616 genes, copy number 5 (within-gene range 0–5) (broad region; genes not listed).
- chr3:93,843,764–118,810,836, 329 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr3:120,448,974–122,793,831, 51 genes, copy number 5 (within-gene range 3–5): AC126182.3, AC126182.1, AC126182.2, NDUFB4, HGD, RABL3, MTCO1P29, MTCO2P29, GTF2E1, NAP1L1P3, AC072026.2, LINC02049, AC072026.3, STXBP5L, AC072026.1, MIR5682, AC078857.1, AC079841.1, AC079841.2, POLQ, RPL7AP11, ARGFX, FBXO40, HCLS1, RN7SL172P, RNU4-62P, GOLGB1, IQCB1, EAF2, SLC15A2, ILDR1, Y_RNA, CD86, AC068630.1, CASR, HNRNPA1P23, CSTA, CCDC58, FAM162A, WDR5B, AC083798.2, AC083798.1, KPNA1, AC096861.1, AC096861.2, PARP9, DTX3L, PARP15, EIF4BP8, PARP14, HSPBAP1.
- chr7:63,843,314–65,770,810, 95 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).
- chr8:139,460,062–145,066,685, 210 genes, copy number 5 (broad region; genes not listed).
- chr11:74,330,316–74,398,433, 1 gene, copy number 5 (within-gene range 4–5): PGM2L1.
- chr11:74,397,549–78,582,156, 135 genes, copy number 5 (broad region; genes not listed).
- chr13:79,311,824–114,337,626, 444 genes, copy number 6 (broad region; genes not listed).
- chr14:18,333,726–21,699,151, 202 genes, copy number 5 (broad region; genes not listed).
- chr17:9,250,471–9,576,591, 1 gene, copy number 6 (within-gene range 4–6): STX8.
- chr17:9,452,197–10,623,886, 29 genes, copy number 6: AC087501.1, AC087501.2, AC087501.3, AC087501.4, CFAP52, RPL19P18, AC118755.2, USP43, AC118755.1, AC027045.2, DHRS7C, AC027045.1, GSG1L2, AC027045.3, GLP2R, NPM1P45, RCVRN, GAS7, RPS27AP1, AC005291.2, MYH13, AC005291.1, AC005323.2, MYHAS, MYH8, MYH4, MYH1, MYH2, AC005323.1.
- chr17:11,953,889–22,706,703, 436 genes, copy number 6 (broad region; genes not listed).
- chr19:23,304,991–23,395,471, 1 gene, copy number 5 (within-gene range 2–5): ZNF91.
- chr19:23,380,317–23,512,656, 6 genes, copy number 5: BNIP3P8, CDC42EP3P1, LINC01224, VN1R92P, AC074140.1, ZNF725P.
- chr19:27,983,032–30,872,507, 54 genes, copy number 5: AC005357.1, AC010511.1, AC020905.1, AC005580.1, AC093074.1, AC005307.1, AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1, MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, AC011505.1, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5, AC005597.1, ZNF536, AC011504.1, AC011478.1, AC011507.1.

Autosomal genes at a single copy (total copy number 1): 1,051. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
